Somatic mutation profile of tumor specimen TCGA-D1-A2G6-01A (aliquot TCGA-D1-A2G6-01A-11D-A17D-09) from TCGA case TCGA-D1-A2G6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.5 years (19,547 days).
Specimen TCGA-D1-A2G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cd624f3-3561-46e7-93a5-4a02fbd3ec3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A2G6-10A (Blood Derived Normal), aliquot TCGA-D1-A2G6-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e88312bc-195c-43d2-81e4-ee7c7d308292

The open-access MAF lists 87 somatic variants for this specimen: 59 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 26, Nonsense Mutation 5, Frame Shift Del 3, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2C | c.4441C>T p.R1481* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs587777073, CM126215, COSV51431986; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ADRA2A | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701381; called by muse, mutect2, varscan2
- AHI1 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1425174262, COSV99661696; called by muse, mutect2, varscan2
- ASB2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100279160; called by muse, mutect2, varscan2
- C1S | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs377093428; called by muse, mutect2, varscan2
- CAMSAP1 | c.4267C>A p.Q1423K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV100409477; called by muse, mutect2
- CAPN5 | c.1994G>A p.G665D (on ENST00000456580; = p.G625D on NM_004055.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99581573; called by muse, mutect2, varscan2
- CCDC178 | c.1656+1G>A p.X552_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100282753; called by muse, mutect2
- CLDN3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs781958238; called by muse, mutect2
- CLHC1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs766740421, COSV100811466; called by muse, mutect2, varscan2
- CPNE7 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99254434; called by muse, mutect2, varscan2
- CPXM2 | c.445T>G p.F149V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as COSV53862051, COSV53862935; called by muse, mutect2, varscan2
- CRIM1 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as COSV99752014, COSV99754903; called by muse, mutect2, varscan2
- CRNN | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs570045971, COSV99663820; called by muse, mutect2, varscan2
- CYFIP2 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs1043836870, COSV100555319; called by muse, mutect2, varscan2
- DDX50 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as rs201925377, COSV65292212; called by muse, mutect2, varscan2
- ESCO1 | c.1855T>A p.C619S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99331715; called by muse, mutect2, varscan2
- FAM153A | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | catalogued as COSV100646879; called by muse, mutect2, varscan2
- FAM172A | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as rs1419526753, COSV67934331; called by muse, mutect2, varscan2
- FHL3 | c.161T>A p.L54Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100885026; called by muse, mutect2
- FLG | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs770321911, COSV64247792; called by muse, mutect2, varscan2
- FLOT2 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477537660, COSV101204734; called by muse, mutect2, varscan2
- FURIN | c.758G>C p.S253T | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99184598; called by muse, mutect2, varscan2
- GGCT | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371796444; called by muse, mutect2, varscan2
- GNAL | c.700G>A p.V234I (on ENST00000269162 / NM_001142339.3; = p.V311I on NM_182978.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM165376, COSV52333987; called by muse, mutect2, varscan2
- GPR84 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as rs779186405, COSV57209564; called by muse, mutect2, varscan2
- HSPA12A | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.174); catalogued as COSV100979691; called by muse, mutect2, varscan2
- ITPK1 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99968076; called by muse, mutect2, varscan2
- JCAD | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs772929418, COSV64757781; called by muse, mutect2, varscan2
- JPH2 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778739555, COSV65901621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA6 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV99768195; called by muse, mutect2, varscan2
- KCNQ3 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.075); catalogued as rs773672399, COSV66468956, COSV66473047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNT2 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV54069705, COSV99650643; called by muse, mutect2, varscan2
- KMT2C | c.13462G>A p.A4488T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753793539, COSV51422873, COSV51455379; called by muse, mutect2, varscan2
- LDHD | c.1121G>C p.W374S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100096508, COSV55580378; called by muse, mutect2, varscan2
- LZTS1 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1331458162, COSV99742501; called by muse, mutect2, varscan2
- MAB21L3 | c.1001T>A p.L334H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101046248; called by muse, mutect2, varscan2
- MEIS2 | c.916G>A p.E306K (on ENST00000561208 / NM_170675.5; = p.E293K on NM_002399.3) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54946332; called by muse, mutect2, varscan2
- NAGK | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99730407; called by muse, mutect2, varscan2
- NEBL | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs367986765, COSV65802789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKAP | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as rs1486378790, COSV65055893; called by muse, mutect2
- NRAP | c.3017C>T p.T1006I (on ENST00000359988 / NM_001322945.2; = p.T971I on NM_006175.4) | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1216613916, COSV100748187; called by muse, mutect2, varscan2
- OR2B6 | c.228T>G p.C76W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV99773508; called by muse, mutect2
- OR2M2 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV100677130; called by muse, varscan2
- PCDHB8 | c.2281G>T p.G761W | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99175165; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2
- PCLO | c.13868A>C p.Q4623P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100426051; called by muse, mutect2, varscan2
- PLEK | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.275); catalogued as rs144599110, COSV99310740; called by muse, mutect2, varscan2
- RNF113B | c.71del p.K24Sfs*131 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as rs752349921; called by mutect2, pindel, varscan2
- RPS6KA2 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748224061, COSV99689866; called by muse, mutect2, varscan2
- SECISBP2 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100068767; called by muse, mutect2, varscan2
- SPEF2 | c.4417C>T p.R1473* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as rs759691682, COSV57428311; called by muse, mutect2, varscan2
- TKFC | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs764399198, COSV67523643, COSV67523889; called by muse, mutect2, varscan2
- UBAP2 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as rs757022773, COSV100670767, COSV62545130; called by muse, mutect2, varscan2
- UBASH3A | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.922); catalogued as rs982276714, COSV99369085; called by muse, mutect2, varscan2
- VPS13B | c.11033C>T p.P3678L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749689354, COSV100660407; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs771899177; called by mutect2, pindel
- ADAMTS2 | c.3150C>T p.P1050= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs374907597; called by muse, mutect2, varscan2
- ADGRG5 | c.1143C>T p.Y381= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs752872934, COSV100446309; called by muse, mutect2, varscan2
- AFTPH | c.2499C>G p.P833= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99480190, COSV99481136; called by muse, mutect2, varscan2
- ANAPC5 | c.942C>T p.F314= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs369385246; called by muse, mutect2
- ARHGEF2 | c.300G>A p.K100= (on ENST00000361247 / NM_001162383.2; = p.K73= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100559845; called by muse, mutect2, varscan2
- CATSPERG | c.1911C>T p.F637= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99285911; called by muse, mutect2, varscan2
- CEACAM5 | c.780C>T p.H260= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs781882470, COSV99703666; called by muse, mutect2, varscan2
- DBX1 | c.180C>T p.T60= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1353303622, COSV99910058; called by muse, varscan2
- EHBP1L1 | c.960G>C p.G320= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100499547; called by muse, mutect2, varscan2
- EYA2 | c.72T>G p.R24= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100426348; called by muse, mutect2, varscan2
- HCFC1 | c.1056C>T p.C352= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV100128215; called by muse, mutect2
- HERC1 | c.14562C>T p.A4854= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1566934536, COSV101496271; called by muse, mutect2, varscan2
- KRTAP22-1 | c.51C>T p.G17= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100588878; called by muse, mutect2
- LDHAL6B | c.630C>T p.S210= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs192955192, COSV55683307; called by muse, mutect2, varscan2
- MYOZ1 | c.723G>A p.Q241= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100831744; called by muse, mutect2
- NDE1 | c.618G>A p.V206= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100706558; called by muse, mutect2
- NLRP1 | c.249C>T p.C83= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs753714957, COSV99332577; called by muse, mutect2, varscan2
- NUP210 | c.1527C>T p.I509= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs113753878, COSV99595298; called by muse, mutect2, varscan2
- NWD1 | c.4059C>T p.S1353= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs776166331, COSV60340942; called by muse, mutect2, varscan2
- PCDHB5 | c.2250C>T p.Y750= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs374460300, COSV50676756; called by muse, mutect2, varscan2
- PCDHGA2 | c.1269C>T p.T423= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs529728428, COSV99527979; called by muse, mutect2, varscan2
- PCDHGA3 | c.2007C>T p.P669= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs540686515, COSV53893148; called by muse, mutect2, varscan2
- PTPRZ1 | c.6081C>T p.F2027= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV101099196; called by muse, mutect2, varscan2
- TMEM89 | c.321C>T p.C107= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs753368260, COSV100257902; called by muse, mutect2, varscan2
- TTC16 | c.537T>C p.C179= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1481344308, COSV100076629; called by muse, mutect2, varscan2
- ZNF536 | c.600C>T p.H200= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100834500; called by muse, mutect2, varscan2
- MIR758 | n.63G>T | RNA (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31011C>T | Intron (SNP) | VAF 23/38 reads (61%) | catalogued as rs773794462, COSV55159461; called by muse, mutect2, varscan2
